CCDI case PBBHCR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/225f7a4f-f9dd-45d4-ab6a-5b2269ee1284

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Medulloepithelioma, NOS: ICD-O-3 morphology code: 9501/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 12.3 years (4,503 days).

Biospecimens (3 samples)
- Sample 0D88RM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D88RN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0D88RQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
